Surgical pathology report (de-identified scan), TCGA case TCGA-KL-8337, project TCGA-KICH (Kidney Chromophobe), tissue source site MSKCC, specimen TCGA-KL-8337-01A (Primary Tumor).

[page 1 of 3]
Clinical Diagnosis & History:

Rt kidney mass.

Specimens Submitted:

1: SP: Kidney, right and perihilar nodes and right liver, radical nephrectomy, liver wedge resection, and lymph node dissection

2: SP: Lymph node, paracaval, excision

DIAGNOSIS:

1. SP: Kidney, right and perihilar nodes and right liver, radical nephrectomy, liver wedge resection, and lymph node dissection

Tumor Type:

Renal cell carcinoma - Chromophobe type

Tumor Size:

Greatest diameter is 10.5 cm.

Local Invasion (for renal cortical types):

Not Identified

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not involved

Liver is not involved

Lymph Nodes:

Free of tumor

Number of nodes examined:1

Staging for renal cell carcinoma/oncocytoma:

pT2 Tumor >7.0 cm in greatest dimension limited to the kidney

2. SP: Lymph node, paracaval, excision

Lymph Nodes:

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

Not involved
Number of nodes examined:1

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Gross Description:

1). The specimen is received fresh labeled "Right kidney, Perihilar nodes, wedge resection right liver" and consists of a kidney with attached ureter, renal vessels, perinephric fat, portion of liver, and adrenal gland. The total post fixation weight of the specimen is 900 g. The overall dimensions of the specimen are 16.5 x 12 x 10.5 cm. The attached ureter measures 3.5 cm in length and 0.4 cm in diameter. The attached renal vein measures 1.0 cm in length and 0.9 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. An adrenal gland is identified, measuring 5 x 2.3 x 0.7 cm. On cut section of the adrenal gland, it shows an unremarkable bright orange cortex measuring up to 0.3 cm in thickness. The segment of liver, which is identified on the upper pole of the kidney, measures 6.5 x 3.2 x 0.9 cm. The resected margins of the liver are inked blue. The kidney is inked black and bivalved to reveal a markedly necrotic pink tan tumor measuring 10.5 x 9.5 x 9.5 cm. The tumor extends from the upper pole to the mid pole of the kidney, and on cut section abuts the black inked surface and is located 0.4 cm the blue inked surface. Further sectioning through the tumor shows a septated cystic appearance, and focal hemorrhagic calcified areas. The tumor appears to be well-circumscribed, and impinges on but does not show definite involvement of the renal pelvis and collecting ducts, renal vein, and sinus fat. Sections through the remainder of the kidney reveal a pink brown parenchyma, with a well-defined corticomedullary junction. The cortex measures 2.5 cm and the calyces appear normal. On complete opening of the ureter, renal pelvis, and collecting ducts, they show unremarkable white-tan mucosa. A single lymph node is identified in the perinephric fat, measuring 1.5 x 1.5 cm in greatest dimensions. The specimen is photographed. Representative sections are submitted for TPS and for permanent sections.

Summary of sections:

UM - ureteral margin
VM-vessel margins
LN-lymph node, serially sectioned
T-- tumor
TSF -- tumor with sinus fat
TA-tumor and adrenal
TL-tumor and liver
TP-tumor and renal pelvis and collecting ducts
TV-tumor and adjacent renal vein
TC-tumor and black inked surface
TN-tumor and normal kidney
RS-representative sections of uninvolved kidney parenchyma
ADR-representative sections of adrenal gland

2). The specimen is received in formalin, labeled "Paracaval lymph nodes" and consists of a single pink-tan, fatty lymph node measuring 2.7 x 2 x 1 cm. The lymph node is dissected into four pieces and entirely submitted.

Summary of sections:

BLN- dissected in four pieces (lymph node)

Summary of Sections:

Part 1: SP: Kidney, right and perihilar nodes and right liver, radical nephrectomy, liver wedge resection, and lymph node dissection

Block	Sect. Site	PCs
-------	------------	-----

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

1	ADR	1
2	In	2
1	RS	1
3	T	3
2	TA	2
2	TC	2
2	TL	2
1	TN	1
2	TP	2
2	TSF	2
2	TV	2
1	um	1
1	vm	1

Part 2: SP: Lymph node, paracaval, excision

Block	Sect. Site	PCs
4	BLN	4

Source: NCI Genomic Data Commons file 07c2a129-09b6-4f8a-b624-81e4cdaa08dd (TCGA-KL-8337.83B8B92E-2989-47C1-9CED-6614F63B8CAA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).